Somatic mutation profile of tumor specimen TCGA-AD-5900-01A (aliquot TCGA-AD-5900-01A-11D-1650-10) from TCGA case TCGA-AD-5900, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 67.8 years (24,776 days).
Specimen TCGA-AD-5900-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84699ff7-ff19-4ce2-9954-04f02e16b732.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-5900-10A (Blood Derived Normal), aliquot TCGA-AD-5900-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2376d52e-18c5-4078-ae37-554bee0fe700

The open-access MAF lists 1,800 somatic variants for this specimen: 1,352 protein-altering or splice-affecting, 410 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 931, Silent 410, Frame Shift Del 236, Frame Shift Ins 71, Nonsense Mutation 57, Splice Site 25, In Frame Del 18, Intron 17, RNA 9, Splice Region 9, 3'UTR 5, Translation Start Site 4.

Variants (750 of 1,800; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.2161-1G>A p.X721_splice | Splice Site (SNP) | VAF 15/64 reads (23%) | catalogued as rs1401924846, COSV100933077; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.2617C>T p.R873* | Nonsense Mutation (SNP) | VAF 51/168 reads (30%) | catalogued as rs137852748, CM002242, COSV65808086; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CTC1 | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs202138550, CM121576, COSV59852744; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCC | c.3649A>G p.M1217V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1057519058, COSV71442075; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGD1 | c.527del p.P176Hfs*39 | Frame Shift Del (DEL) | VAF 24/37 reads (65%) | catalogued as rs756586058; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 36/144 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs397515538; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SETD2 | c.4715+1G>A p.X1572_splice | Splice Site (SNP) | VAF 38/122 reads (31%) | hotspot (GDC flag); catalogued as COSV57431126, COSV57439397; called by muse, mutect2, varscan2
- TRMU | c.880del p.R294Gfs*12 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs1490906786; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- A4GNT | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV52630300; called by muse, mutect2, varscan2
- AADACL2 | c.253_255del p.T85del | In Frame Del (DEL) | VAF 90/364 reads (25%) | catalogued as rs755567405; called by pindel, varscan2
- ABCA3 | c.4466G>A p.R1489H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs557707047, COSV57051383; ClinVar: uncertain significance; called by mutect2, varscan2
- ABCA8 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1265324567, COSV52213908; called by muse, mutect2, varscan2
- ABCB1 | c.3674G>A p.R1225H | Missense Mutation (SNP) | VAF 93/359 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs779103120, COSV55949408; called by muse, mutect2, varscan2
- ABCB1 | c.1790T>C p.V597A | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV55965401; called by muse, mutect2, varscan2
- ABCC10 | c.1505T>C p.L502P (on ENST00000372530 / NM_001198934.2; = p.L459P on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55094806; called by muse, mutect2, varscan2
- ABCC5 | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751038876, COSV55597409; called by muse, mutect2, varscan2
- ABCC8 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs748433658, COSV56858840; called by muse, mutect2, varscan2
- ABI3BP | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 33/354 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV99425956; called by muse, mutect2
- AC097636.1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs559038253, COSV71309693; called by muse, mutect2, varscan2
- ACACB | c.4468C>T p.R1490C | Missense Mutation (SNP) | VAF 80/339 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756806908, COSV58138346; called by muse, mutect2, varscan2
- ACADM | c.217-2A>G p.X73_splice | Splice Site (SNP) | VAF 100/382 reads (26%) | catalogued as COSV63721450; called by muse, mutect2, varscan2
- ACAN | c.1754G>T p.R585L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV61370949; called by muse, mutect2, varscan2
- ACIN1 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs747738693, COSV52982973; called by muse, mutect2, varscan2
- ACIN1 | c.3359del p.P1120Hfs*110 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs756288275; called by mutect2, pindel, varscan2
- ACLY | c.2701G>A p.G901R | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100709518, COSV61253654; called by muse, mutect2, varscan2
- ACMSD | c.922A>G p.M308V | Missense Mutation (SNP) | VAF 80/372 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1317921999, COSV51610136; called by muse, mutect2, varscan2
- ACSF3 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs200536797, COSV58082413; called by muse, mutect2, varscan2
- ACSL1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as rs200424498, COSV55664168; called by muse, mutect2, varscan2
- ADAM22 | c.2574T>C p.T858= | Splice Region (SNP) | VAF 24/132 reads (18%) | catalogued as COSV55992326; called by muse, mutect2, varscan2
- ADAM8 | c.1424T>C p.L475P | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101291638; called by muse, mutect2, varscan2
- ADAMTS13 | c.3298C>A p.L1100I | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.406); catalogued as COSV52472049; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2921C>T p.A974V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs777540083, COSV99717810; called by mutect2, varscan2
- ADD1 | c.2153del p.K718Rfs*11 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | catalogued as rs746468920; called by mutect2, pindel, varscan2
- ADGRA2 | c.1573del p.A525Pfs*12 | Frame Shift Del (DEL) | VAF 30/59 reads (51%) | catalogued as rs760256806, COSV59443632; called by mutect2, pindel, varscan2
- ADGRB1 | c.3961G>A p.G1321S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.174); catalogued as rs774828542, COSV60091234; called by muse, mutect2, varscan2
- ADGRB2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as rs754770509, COSV57079700; called by muse, mutect2, varscan2
- ADGRL1 | c.1454T>C p.V485A (on ENST00000340736 / NM_001008701.3; = p.V480A on NM_014921.5) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100529360; called by muse, mutect2, varscan2
- ADGRV1 | c.7523G>T p.R2508M | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as rs1019937283, COSV101315689; called by muse, mutect2
- ADORA1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1218495662, COSV58813581; called by muse, mutect2, varscan2
- AFAP1L2 | c.773A>G p.Q258R | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1162865622, COSV58419229; called by muse, mutect2
- AFF1 | c.2659C>T p.R887W | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs376847723; called by muse, mutect2, varscan2
- AFF4 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 109/353 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1205979521, COSV54794177; called by muse, mutect2, varscan2
- AGBL5 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as rs757496484, COSV64080985; called by muse, mutect2, varscan2
- AGO1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV64594678; called by muse, mutect2, varscan2
- AGPAT2 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs746314526, COSV58248980; called by muse, mutect2, varscan2
- AHNAK2 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs767704152, COSV60918529; called by muse, mutect2, varscan2
- AK7 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV50884573; called by muse, varscan2
- AKAP4 | c.277-3del | Splice Region (DEL) | VAF 30/69 reads (43%) | catalogued as rs1321821014; called by mutect2, pindel, varscan2
- AKAP6 | c.6623C>T p.A2208V | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV55236391; called by muse, mutect2, varscan2
- AKT1S1 | c.173C>T p.A58V (on ENST00000344175 / NM_001098633.4; = p.A78V on NM_032375.5) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.14); catalogued as rs375398248; called by muse, mutect2, varscan2
- AL021546.1 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.885); catalogued as COSV99984825; called by muse, mutect2
- ALDH1L1 | c.295del p.R99Gfs*62 | Frame Shift Del (DEL) | VAF 33/129 reads (26%) | catalogued as rs755422577, COSV99856805; called by mutect2, pindel
- ALDH9A1 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61341740; called by muse, mutect2, varscan2
- ALMS1 | c.1259A>T p.E420V | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV52523809; called by muse, mutect2, varscan2
- ALMS1 | c.3185A>G p.Q1062R | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs373066945, COSV52523818; called by muse, mutect2, varscan2
- ALOX15B | c.104del p.P35Hfs*21 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs747925269; called by mutect2, pindel, varscan2
- ALPI | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1158171138, COSV55013640; called by muse, mutect2, varscan2
- AMBP | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs369822351; called by muse, varscan2
- AMIGO2 | c.1293G>T p.Q431H | Missense Mutation (SNP) | VAF 34/900 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV99873519; called by muse, mutect2
- ANAPC7 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs1212920721, COSV71444087; called by muse, mutect2, varscan2
- ANGPTL2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.166); catalogued as rs1326631657, COSV52222130; called by muse, mutect2, varscan2
- ANK3 | c.11156G>A p.R3719H | Missense Mutation (SNP) | VAF 91/277 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs748061808, COSV55043282; called by muse, mutect2, varscan2
- ANKH | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs768077784, COSV52481493, COSV52484616; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4594del p.R1532Gfs*5 | Frame Shift Del (DEL) | VAF 37/193 reads (19%) | catalogued as COSV51845823; called by mutect2, pindel, varscan2
- ANKMY1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as rs373523989; called by muse, mutect2, varscan2
- ANKRD53 | c.617+1G>A p.X206_splice | Splice Site (SNP) | VAF 27/100 reads (27%) | catalogued as rs150139540; called by muse, mutect2, varscan2
- ANXA2 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 102/341 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1448493904, COSV60319040; called by muse, mutect2, varscan2
- AP2A2 | c.2006del p.P669Lfs*67 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as rs770443312, COSV59961800; called by mutect2, pindel, varscan2
- AP3S2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs774639100, COSV60520094; called by muse, varscan2
- APC | c.3616A>G p.S1206G | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs901866497, COSV57388288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APCDD1L | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs554715845, COSV64488063; called by muse, mutect2, varscan2
- APOA4 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as rs147626624; called by muse, mutect2, varscan2
- ARHGAP1 | c.730G>T p.V244F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV61736287; called by muse, mutect2, varscan2
- ARHGAP15 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs758104156, COSV54484212; called by muse, mutect2, varscan2
- ARHGAP24 | c.842A>G p.N281S (on ENST00000395184 / NM_001025616.3; = p.N188S on NM_031305.3) | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51994510; called by muse, mutect2, varscan2
- ARHGAP32 | c.5279G>A p.R1760H (on ENST00000310343 / NM_001378025.1; = p.R1411H on NM_014715.4) | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs550791905, COSV59845479; called by muse, mutect2, varscan2
- ARHGAP33 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); catalogued as rs780441014, COSV50135591, COSV50193304; called by muse, mutect2, varscan2
- ARHGAP35 | c.4255C>T p.R1419C | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768711914, COSV68330192; called by muse, mutect2, varscan2
- ARHGEF10 | c.3700G>T p.A1234S (on ENST00000398564; = p.A1209S on NM_014629.4) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV50685413; called by muse, mutect2
- ARHGEF10L | c.3712G>A p.V1238M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV51442216; called by muse, mutect2, varscan2
- ARHGEF15 | c.36del p.T13Rfs*169 | Frame Shift Del (DEL) | VAF 28/111 reads (25%) | catalogued as rs1338358886; called by mutect2, pindel, varscan2
- ARID5A | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV62591866; called by muse, mutect2, varscan2
- ARL14EP | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 109/374 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.212); catalogued as rs199566595; called by muse, mutect2, varscan2
- ARL4D | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60721796; called by muse, mutect2
- ARMCX2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs781887055, COSV57529506; called by muse, mutect2, varscan2
- ARPC4 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55029906; called by muse, mutect2
- ARRDC1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58382924; called by muse, mutect2, varscan2
- ASAH2B | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 244/914 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs372083437, COSV51767985; called by muse, varscan2
- ASAP3 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); catalogued as COSV60878502; called by muse, mutect2, varscan2
- ASCC2 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs374537193; called by muse, mutect2, varscan2
- ATG2A | c.4634C>T p.T1545M | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs977945889, COSV65969107; called by muse, mutect2, varscan2
- ATP10A | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs777738173, COSV63516773; called by muse, mutect2, varscan2
- ATP13A5 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201429023, COSV60868271; called by muse, mutect2, varscan2
- ATP13A5 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV60876525; called by muse, mutect2, varscan2
- ATP2A2 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV58048248; called by muse, mutect2, varscan2
- ATP2A3 | c.1712dup p.R572Kfs*35 | Frame Shift Ins (INS) | VAF 11/49 reads (22%) | catalogued as rs779330933; called by mutect2, pindel, varscan2
- ATP2B2 | c.1079A>C p.D360A (on ENST00000352432; = p.D326A on NM_001683.5) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as COSV59499143, COSV59508782; called by muse, mutect2, varscan2
- ATP2B3 | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 112/195 reads (57%) | catalogued as COSV54864051; called by muse, mutect2, varscan2
- ATP6AP1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs375162515, COSV63895824; called by muse, mutect2, varscan2
- ATRN | c.1379T>C p.V460A | Missense Mutation (SNP) | VAF 29/637 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV99496868; called by muse, mutect2
- ATXN10 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 102/366 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs150548393; called by muse, mutect2, varscan2
- ATXN3 | c.575T>A p.I192N | Missense Mutation (SNP) | VAF 94/382 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61498245; called by muse, varscan2
- ATXN7L2 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs759451895, COSV60205734; called by muse, mutect2, varscan2
- AXIN1 | c.792del p.G265Efs*149 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as COSV51989295; called by mutect2, pindel
- AXIN2 | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as rs765845684, COSV61057847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAHCC1 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.211); catalogued as COSV57034533; called by muse, mutect2
- BAIAP2L1 | c.858del p.A287Lfs*11 | Frame Shift Del (DEL) | VAF 39/166 reads (23%) | catalogued as COSV50058748; called by mutect2, varscan2
- BAZ1A | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV62412389; called by muse, varscan2
- BAZ2A | c.3797A>G p.Q1266R | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV51644969; called by muse, mutect2
- BCAT1 | c.59A>C p.E20A | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV53918759; called by muse, mutect2, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs751794665; called by mutect2, varscan2
- BICDL1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57492425; called by muse, mutect2, varscan2
- BLOC1S2 | c.296C>A p.A99D | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.815); catalogued as COSV62489551; called by muse, mutect2, varscan2
- BMP1 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV60475848, COSV60484551; called by muse, mutect2, varscan2
- BMP10 | c.382del p.L128Sfs*29 | Frame Shift Del (DEL) | VAF 14/146 reads (10%) | catalogued as COSV54896691; called by mutect2, pindel
- BMP4 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 92/331 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV55417455; called by muse, mutect2, varscan2
- BMPR1B | c.1501A>G p.K501E | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1229797838, COSV52782593; called by muse, mutect2, varscan2
- BOC | c.1332del p.Q445Nfs*66 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as COSV56359238, COSV99848035; called by mutect2, pindel, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD4 | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs368540009; called by muse, mutect2, varscan2
- BRD4 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 45/125 reads (36%) | catalogued as COSV54586032; called by muse, mutect2, varscan2
- BRPF3 | c.2561del p.P854Rfs*6 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | catalogued as rs1413008697, COSV60208966; called by mutect2, pindel, varscan2
- BRPF3 | c.3092C>T p.T1031M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs751035235, COSV60207409; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BSG | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV100344626; called by muse, varscan2
- BST1 | c.618dup p.A207Cfs*4 | Frame Shift Ins (INS) | VAF 25/142 reads (18%) | catalogued as rs761650390; called by mutect2, varscan2
- BTAF1 | c.2417C>A p.A806D | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56440286; called by muse, mutect2, varscan2
- C17orf49 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV101143318; called by muse, mutect2, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 39/218 reads (18%) | catalogued as rs781818365; called by mutect2, varscan2
- C1orf127 | c.2359del p.A787Pfs*7 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | catalogued as rs1283160262; called by mutect2, pindel, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C22orf15 | c.260A>T p.D87V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV100533580; called by muse, mutect2
- C2CD2 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100298066; called by muse, mutect2, varscan2
- C3 | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.102); catalogued as rs756811072, COSV55574628, COSV55582652; called by muse, mutect2, varscan2
- C4A | c.2669C>A p.P890H | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101418321; called by muse, varscan2
- C4orf46 | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV57016777; called by muse, mutect2, varscan2
- C8A | c.1380+1G>A p.X460_splice | Splice Site (SNP) | VAF 14/242 reads (6%) | catalogued as COSV63486802; called by muse, mutect2
- CA5B | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 52/651 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as COSV100590706; called by muse, mutect2, varscan2
- CA9 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV61408001; called by muse, mutect2, varscan2
- CACNA1C | c.1412C>T p.T471I | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV59780764; called by muse, mutect2, varscan2
- CACNA1D | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV55454913; called by muse, mutect2, varscan2
- CACNA1D | c.2803C>A p.L935M (on ENST00000350061 / NM_001128840.3; = p.L955M on NM_000720.4) | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV99857290; called by muse, mutect2, varscan2
- CACNA1I | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60819937; called by muse, mutect2, varscan2
- CACNA2D4 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs751635362, COSV54963079; called by muse, mutect2, varscan2
- CAMK4 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 60/790 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99998719; called by muse, mutect2
- CAMLG | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV51805811; called by muse, mutect2, varscan2
- CAND2 | c.2329C>A p.L777I (on ENST00000456430 / NM_001162499.2; = p.L684I on NM_012298.3) | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV55995494; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel
- CARMIL3 | c.2375A>G p.H792R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.444); catalogued as COSV57728784; called by muse, mutect2
- CASKIN2 | c.2716A>G p.T906A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV100050250; called by muse, mutect2
- CASP7 | c.375del p.A126Lfs*17 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | catalogued as rs1247046723, COSV61881818; called by mutect2, pindel, varscan2
- CATSPERD | c.1213A>G p.M405V | Missense Mutation (SNP) | VAF 97/324 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58467930; called by muse, mutect2, varscan2
- CATSPERD | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs953483515, COSV58467941; called by muse, mutect2, varscan2
- CAVIN1 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 92/402 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63811874; called by muse, mutect2, varscan2
- CBARP | c.743G>A p.G248D (on ENST00000382477; = p.G228D on NM_152769.3) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1466760741, COSV99289458; called by muse, mutect2, varscan2
- CCDC134 | c.226-1G>T p.X76_splice | Splice Site (SNP) | VAF 9/30 reads (30%) | catalogued as COSV55389184; called by muse, mutect2, varscan2
- CCDC178 | c.1007C>A p.T336N | Missense Mutation (SNP) | VAF 118/411 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55769806; called by muse, mutect2, varscan2
- CCDC88C | c.3797A>G p.H1266R | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1209840008, COSV66242514; called by muse, mutect2
- CCM2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs781634033, COSV51851107; called by muse, mutect2, varscan2
- CD276 | c.1141A>G p.I381V (on ENST00000318443 / NM_001024736.2; = p.I163V on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.124); catalogued as rs769999909, COSV59206058; called by muse, mutect2, varscan2
- CDC40 | c.870C>T p.G290= | Splice Region (SNP) | VAF 93/422 reads (22%) | catalogued as rs559751620, COSV57010223; called by muse, mutect2, varscan2
- CDCA7 | c.523C>T p.R175W (on ENST00000347703 / NM_145810.3; = p.R254W on NM_031942.5) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as rs145479884; called by muse, mutect2, varscan2
- CDCA7 | c.1072G>A p.A358T (on ENST00000347703 / NM_145810.3; = p.A437T on NM_031942.5) | Missense Mutation (SNP) | VAF 120/471 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as COSV60721993; called by muse, varscan2
- CDH12 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 95/421 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs143124599, COSV66443827; called by muse, mutect2, varscan2
- CDH16 | c.1686del p.K563Sfs*22 | Frame Shift Del (DEL) | VAF 27/110 reads (25%) | catalogued as rs776664434; called by mutect2, pindel, varscan2
- CDH23 | c.7596G>T p.M2532I | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV56494157; called by muse, mutect2, varscan2
- CDH23 | c.8014C>A p.L2672I | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.177); catalogued as COSV56494174; called by muse, mutect2, varscan2
- CDH26 | c.2233G>A p.A745T (on ENST00000348616 / NM_177980.4; = p.A78T on NM_021810.6) | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1310105947, COSV54856799; called by muse, mutect2, varscan2
- CDK11A | c.325+2T>C p.X109_splice (on ENST00000378633 / NM_001313896.2; = p.C109= on NM_024011.4) | Splice Site (SNP) | VAF 53/202 reads (26%) | catalogued as rs1236142131, COSV62267137; called by muse, mutect2, varscan2
- CDK12 | c.4382dup p.T1463Nfs*50 (on ENST00000447079 / NM_016507.4; = p.T1454Nfs*50 on NM_015083.3) | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | catalogued as rs760014508; called by mutect2, varscan2
- CDK5RAP2 | c.3530T>C p.V1177A | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV62578062; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3035del p.P1012Lfs*62 | Frame Shift Del (DEL) | VAF 40/174 reads (23%) | catalogued as COSV100575455; called by mutect2, pindel, varscan2
- CDR2 | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV51677768; called by muse, mutect2, varscan2
- CDR2L | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV61501945; called by muse, mutect2, varscan2
- CELA3B | c.440C>A p.A147D | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV100448655; called by muse, mutect2
- CENPE | c.6238del p.R2080Gfs*3 | Frame Shift Del (DEL) | VAF 67/242 reads (28%) | catalogued as COSV54379548; called by mutect2, pindel, varscan2
- CEP350 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 60/198 reads (30%) | catalogued as COSV62486180; called by muse, mutect2, varscan2
- CEP85 | c.1636_1638del p.S546del | In Frame Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs1377767876; called by pindel, varscan2
- CES1 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV62090870; called by muse, mutect2
- CFAP100 | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs759274696, COSV61504556; called by muse, mutect2, varscan2
- CFAP43 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs145913363, COSV53376560; called by muse, mutect2, varscan2
- CFAP74 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99574020; called by muse, mutect2
- CHD1 | c.629del p.K210Rfs*39 | Frame Shift Del (DEL) | VAF 96/457 reads (21%) | catalogued as COSV52337505; called by mutect2, pindel, varscan2
- CHD2 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as COSV59122901; called by muse, mutect2, varscan2
- CHD4 | c.4175C>T p.A1392V (on ENST00000357008 / NM_001363606.2; = p.A1405V on NM_001273.5) | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58912437; called by muse, mutect2, varscan2
- CHD8 | c.1988C>T p.T663I (on ENST00000646647 / NM_001170629.2; = p.T384I on NM_020920.4) | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as COSV67873018; called by muse, mutect2, varscan2
- CHRM1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV61008052; called by muse, mutect2, varscan2
- CHRM2 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100280981; called by muse, mutect2, varscan2
- CHRNA5 | c.639dup p.D214* | Frame Shift Ins (INS) | VAF 34/179 reads (19%) | catalogued as rs1202847637; called by mutect2, varscan2
- CHSY1 | c.666del p.P223Lfs*3 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | catalogued as rs762321510; called by pindel, varscan2
- CIAO1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as rs903722571, COSV51499171; called by muse, mutect2, varscan2
- CISH | c.653G>A p.S218N (on ENST00000348721 / NM_145071.4; = p.S235N on NM_013324.6) | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV62295628; called by muse, mutect2, varscan2
- CIZ1 | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | catalogued as COSV52971325; called by muse, mutect2, varscan2
- CLCA1 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52332136; called by muse, mutect2, varscan2
- CLCN3 | c.1062dup p.A355Cfs*17 | Frame Shift Ins (INS) | VAF 248/966 reads (26%) | catalogued as rs1188097023; called by mutect2, varscan2
- CLCNKB | c.1395del p.Y466Mfs*13 | Frame Shift Del (DEL) | VAF 44/146 reads (30%) | catalogued as rs762878606; called by mutect2, pindel, varscan2
- CLEC12B | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 309/642 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV58864649; called by muse, mutect2, varscan2
- CLEC4F | c.1595G>T p.R532M | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV55481969; called by muse, mutect2, varscan2
- CLGN | c.1142_1145del p.N381Ifs*24 | Frame Shift Del (DEL) | VAF 72/353 reads (20%) | catalogued as rs1262458123; called by mutect2, pindel, varscan2
- CLK3 | c.547C>T p.R183* (on ENST00000395066 / NM_001130028.1; = p.R35* on NM_003992.4) | Nonsense Mutation (SNP) | VAF 30/122 reads (25%) | catalogued as rs1459068786, COSV61413820; called by muse, mutect2, varscan2
- CLMP | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 87/281 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1339521764, COSV71650687; called by muse, mutect2, varscan2
- CLPB | c.497T>G p.L166R | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53634349; called by muse, mutect2, varscan2
- CLSTN2 | c.2230C>T p.R744C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs761770065, COSV71723274; called by muse, mutect2, varscan2
- CLTCL1 | c.2743del p.H915Ifs*56 | Frame Shift Del (DEL) | VAF 36/121 reads (30%) | catalogued as COSV99595525; called by mutect2, pindel, varscan2
- CLUAP1 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as rs749597681, COSV58894223; called by muse, mutect2, varscan2
- CNGB1 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 27/98 reads (28%) | catalogued as COSV51907980; called by muse, mutect2, varscan2
- CNR1 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 44/142 reads (31%) | catalogued as rs770859974, COSV62986433; called by muse, mutect2, varscan2
- CNTNAP2 | c.1670G>T p.R557I | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62244393; called by muse, mutect2, varscan2
- CNTNAP2 | c.3007A>G p.K1003E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as CM157852, COSV62267920; called by muse, mutect2, varscan2
- CNTNAP5 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756000668, COSV70498892; called by mutect2, varscan2
- COL13A1 | c.485del p.P162Lfs*33 | Frame Shift Del (DEL) | VAF 25/104 reads (24%) | catalogued as COSV62567974; called by mutect2, pindel, varscan2
- COL21A1 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs867801414, COSV55154404, COSV55182558; called by muse, mutect2, varscan2
- COL4A4 | c.3684del p.G1230Vfs*58 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | catalogued as rs1348572523, CD1414071, COSV61631407; called by mutect2, pindel, varscan2
- COL4A6 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57880852; called by muse, mutect2, varscan2
- COL9A3 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs531144768, COSV59655677; called by muse, mutect2, varscan2
- COQ10A | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); catalogued as rs757134894, COSV57526137; called by muse, mutect2, varscan2
- COX6C | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 68/111 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as rs746221706, COSV52553295; called by muse, mutect2, varscan2
- CPAMD8 | c.3153del p.H1052Ifs*127 (on ENST00000651564; = p.H1005Ifs*127 on NM_015692.5) | Frame Shift Del (DEL) | VAF 25/98 reads (26%) | catalogued as rs750161916, COSV71597321; called by mutect2, pindel, varscan2
- CPAMD8 | c.1783G>A p.A595T (on ENST00000651564; = p.A548T on NM_015692.5) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV52241179; called by muse, mutect2, varscan2
- CPNE5 | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99782588; called by muse, varscan2
- CPSF1 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 61/78 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV58235898; called by muse, mutect2, varscan2
- CPSF1 | c.1917del p.V640Wfs*20 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as COSV58233476; called by pindel, varscan2
- CPVL | c.821G>A p.C274Y | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.242); catalogued as COSV99605570; called by muse, mutect2
- CPVL | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV99605572; called by muse, mutect2, varscan2
- CRAT | c.495del p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | catalogued as rs772054700, COSV58879005; called by mutect2, varscan2
- CROCC | c.3244C>T p.R1082W | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs201086543, COSV100978116; called by muse, mutect2, varscan2
- CROT | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 102/450 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58977269; called by muse, mutect2, varscan2
- CRYBG2 | c.4697G>A p.S1566N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV57490939; called by muse, mutect2, varscan2
- CS | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57526157; called by muse, mutect2
- CSF3R | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV58973037; called by muse, mutect2, varscan2
- CSMD1 | c.2867A>G p.N956S (on ENST00000520002; = p.N955S on NM_033225.6) | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59395069; called by muse, mutect2, varscan2
- CSRNP3 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as rs141222366; called by muse, mutect2, varscan2
- CTC1 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 63/257 reads (25%) | catalogued as COSV59855770; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTTNBP2 | c.4082T>C p.V1361A | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV50494331; called by muse, mutect2, varscan2
- CUBN | c.5489T>C p.V1830A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV100912347; called by muse, mutect2
- CUL5 | c.2221A>G p.I741V | Missense Mutation (SNP) | VAF 117/462 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as COSV67610410; called by muse, mutect2, varscan2
- CUL7 | c.2064-2A>G p.X688_splice | Splice Site (SNP) | VAF 20/90 reads (22%) | catalogued as rs1462454613, COSV54822964; called by muse, mutect2, varscan2
- CYP11A1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51435350; called by muse, mutect2, varscan2
- CYP2W1 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.108); catalogued as rs1419841946, COSV58271797; called by muse, mutect2, varscan2
- CYP46A1 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as COSV99952538; called by muse, varscan2
- CYP4F22 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54109283; called by muse, mutect2, varscan2
- CYP4V2 | c.571del p.Y191Tfs*7 | Frame Shift Del (DEL) | VAF 70/278 reads (25%) | catalogued as rs1467050790; called by mutect2, varscan2
- CYP51A1 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV50152015; called by muse, mutect2
- DAAM2 | c.3176G>A p.R1059Q (on ENST00000274867 / NM_001201427.2; = p.R1058Q on NM_015345.3) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs370249895, COSV51336886; called by muse, mutect2, varscan2
- DAPK1 | c.3822dup p.Y1275Vfs*64 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | catalogued as rs779681511; called by mutect2, varscan2
- DCAF4L2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 154/241 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1459776004, COSV60476643; called by muse, mutect2, varscan2
- DCHS1 | c.7784T>C p.V2595A | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV100197289; called by muse, varscan2
- DDIAS | c.2212A>G p.S738G | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV61273496; called by muse, mutect2, varscan2
- DDX10 | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59441056; called by muse, mutect2, varscan2
- DDX17 | c.1295A>G p.D432G | Missense Mutation (SNP) | VAF 62/558 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99318656; called by muse, varscan2
- DEFB136 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 169/244 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs267601740, COSV66363813; called by muse, mutect2, varscan2
- DENND10 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 177/691 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1432286206, COSV100341019; called by muse, mutect2, varscan2
- DENND2B | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 86/309 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV100567317; called by muse, varscan2
- DENND2B | c.1283del p.P428Rfs*56 | Frame Shift Del (DEL) | VAF 33/167 reads (20%) | catalogued as COSV58200858; called by mutect2, pindel, varscan2
- DENND5A | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760981468, COSV60233064; called by muse, mutect2, varscan2
- DENND6B | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1256761088, COSV69807159; called by muse, mutect2, varscan2
- DERL1 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 182/264 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52366573; called by muse, mutect2, varscan2
- DHH | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99908790; called by muse, mutect2, varscan2
- DHX32 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752780900, COSV99501502; called by muse, mutect2, varscan2
- DHX8 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs765080067, COSV52257124; called by muse, mutect2, varscan2
- DICER1 | c.3160C>T p.L1054F | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100601921; called by muse, mutect2, varscan2
- DLX4 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99537500; called by muse, mutect2, varscan2
- DNAH1 | c.6028C>T p.P2010S | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV70237614; called by muse, mutect2, varscan2
- DNAH17 | c.11263C>T p.R3755W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148540232; called by muse, mutect2, varscan2
- DNAH17 | c.10129C>A p.L3377M | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67762236; called by muse, mutect2
- DNAH17 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.331); catalogued as rs145896153; called by muse, mutect2, varscan2
- DNAH2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50020974; called by muse, mutect2
- DNAH2 | c.11995C>A p.L3999M | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV66728585; called by muse, mutect2, varscan2
- DNAH3 | c.7407G>A p.W2469* | Nonsense Mutation (SNP) | VAF 99/337 reads (29%) | catalogued as COSV54557404; called by muse, mutect2, varscan2
- DNAH5 | c.1062T>G p.C354W | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV54256945; called by muse, mutect2, varscan2
- DNAH7 | c.3865C>T p.R1289* | Nonsense Mutation (SNP) | VAF 82/311 reads (26%) | catalogued as rs1278736038, COSV56778453; called by muse, mutect2, varscan2
- DNAJC1 | c.1439G>T p.S480I | Missense Mutation (SNP) | VAF 112/410 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV65414437, COSV65414857; called by muse, mutect2, varscan2
- DNAJC13 | c.66del p.K23Sfs*21 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as COSV53450346; called by mutect2, pindel, varscan2
- DNM1 | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV100359710; called by muse, mutect2, varscan2
- DNM2 | c.1864C>T p.R622* (on ENST00000355667 / NM_001005360.3; = p.R618* on NM_004945.3) | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as rs1439919754, COSV58957366; called by muse, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 20/186 reads (11%) | catalogued as rs782552436; called by mutect2, pindel
- DOK7 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.486); catalogued as rs1446844121, COSV60774193; called by muse, mutect2, varscan2
- DOP1A | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 131/441 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764152273, COSV52708215; called by muse, mutect2, varscan2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 51/167 reads (31%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel, varscan2
- DPP6 | c.1234G>A p.D412N (on ENST00000377770 / NM_001364500.2; = p.D350N on NM_001936.5) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.305); catalogued as COSV59649435; called by muse, mutect2
- DPYSL5 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs752901583, COSV56517091; called by muse, mutect2, varscan2
- DRG2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56729651; called by muse, mutect2, varscan2
- DSCAML1 | c.4027G>A p.E1343K (on ENST00000321322; = p.E1283K on NM_020693.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.3); catalogued as rs1273146727, COSV58385650, COSV58404521; called by muse, mutect2, varscan2
- DSP | c.6851G>A p.R2284Q | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.619); catalogued as rs1273566858, COSV65792055; called by muse, mutect2, varscan2
- DST | c.2932T>A p.S978T (on ENST00000361203 / NM_001374722.1; = p.S652T on NM_001723.6) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV55045189; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1171T>A p.F391I | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as rs752516635, COSV50051171; called by muse, mutect2, varscan2
- DYNC2H1 | c.6524G>A p.G2175D | Missense Mutation (SNP) | VAF 78/309 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV62108773; called by muse, mutect2, varscan2
- DZIP1L | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV59523954; called by muse, mutect2, varscan2
- E2F7 | c.314A>G p.K105R | Missense Mutation (SNP) | VAF 268/669 reads (40%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV59740114; called by muse, mutect2, varscan2
- ECM1 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV60875672; called by muse, mutect2, varscan2
- EEA1 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 22/682 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100467348; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62571391; called by muse, mutect2, varscan2
- EFHC2 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV69555843; called by muse, mutect2, varscan2
- EIF3A | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs755084308, COSV64961215; called by muse, mutect2, varscan2
- ELK3 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.952); catalogued as rs1463843968, COSV99957552; called by muse, mutect2, varscan2
- ELN | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV52716552; called by muse, mutect2, varscan2
- ELOC | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 30/528 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.604); catalogued as rs1563677151, COSV53023359; called by muse, mutect2
- ELSPBP1 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60415294; called by muse, mutect2, varscan2
- EMC1 | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 56/163 reads (34%) | catalogued as COSV61887134; called by muse, mutect2, varscan2
- EMILIN1 | c.254del p.C85Lfs*29 | Frame Shift Del (DEL) | VAF 34/133 reads (26%) | catalogued as COSV66695574; called by mutect2, pindel, varscan2
- ENDOV | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV100108489; called by muse, mutect2, varscan2
- ENTPD8 | c.1348G>A p.G450R (on ENST00000371506 / NM_001033113.2; = p.G413R on NM_198585.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs768824242, COSV58163986; called by muse, mutect2, varscan2
- EPB41 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 111/405 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.019); catalogued as rs1327041961, COSV58055207; called by muse, mutect2, varscan2
- EPC2 | c.401T>A p.I134N | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV51550487; called by muse, mutect2, varscan2
- EPG5 | c.7279C>T p.L2427F | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs770854534, COSV56357047; called by muse, mutect2, varscan2
- EPG5 | c.3683C>T p.T1228M | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs556565796, COSV56357058; called by muse, mutect2, varscan2
- EPHA7 | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV65193330; called by muse, mutect2, varscan2
- EPHB6 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1221729726, COSV67421214; called by muse, mutect2, varscan2
- EPPK1 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs560900428, COSV73262471; called by muse, mutect2, varscan2
- EPRS1 | c.3355C>T p.R1119C | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65096944; called by muse, mutect2
- EPS8L1 | c.1187C>T p.S396L (on ENST00000201647 / NM_133180.3; = p.S269L on NM_017729.3) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs868104781, COSV99135902; called by muse, mutect2, varscan2
- ERC2 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs200184138, COSV55666387; called by muse, mutect2, varscan2
- ERI3 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64833919; called by muse, mutect2, varscan2
- ERICH1 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs752885695, COSV50641388; called by muse, mutect2, varscan2
- ERLIN1 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 140/526 reads (27%) | catalogued as COSV64941502; called by muse, varscan2
- ERMN | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 27/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs970886305, COSV101263032; called by muse, mutect2
- ERP44 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 168/637 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs776153086, COSV52430080; called by muse, mutect2, varscan2
- ERVW-1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs758687766, COSV101423821; called by muse, mutect2, varscan2
- ESPL1 | c.4662G>T p.K1554N | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV99229083; called by muse, varscan2
- ETFRF1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 117/565 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); catalogued as COSV61646239; called by muse, mutect2, varscan2
- ETV6 | c.1140G>T p.W380C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765951; called by muse, mutect2, varscan2
- EVC | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.275); catalogued as COSV53839023; called by muse, mutect2, varscan2
- EVI2B | c.802T>C p.S268P | Missense Mutation (SNP) | VAF 109/413 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV58365263; called by muse, mutect2, varscan2
- EVI5 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 194/805 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as COSV100945227, COSV64830729; called by muse, mutect2, varscan2
- EVL | c.351A>G p.G117= (on ENST00000402714 / NM_001330221.2; = p.G119= on NM_016337.3) | Splice Region (SNP) | VAF 38/166 reads (23%) | catalogued as COSV67377377; called by muse, varscan2
- EVL | c.446G>A p.R149H (on ENST00000402714 / NM_001330221.2; = p.R151H on NM_016337.3) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs750787699, COSV67375218; called by muse, mutect2, varscan2
- EVPL | c.4504C>A p.L1502M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV56916919; called by muse, mutect2, varscan2
- EVX2 | c.835C>A p.H279N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.474); catalogued as COSV57965681; called by muse, mutect2, varscan2
- EXOC2 | c.2735C>T p.T912I | Missense Mutation (SNP) | VAF 110/405 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs773976485, COSV100033288; called by muse, varscan2
- EXOSC5 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367849322; called by muse, mutect2, varscan2
- F2 | c.1477C>T p.L493F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as COSV61318044; called by muse, mutect2, varscan2
- FAF1 | c.1647A>C p.E549D | Missense Mutation (SNP) | VAF 115/466 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as COSV65644801; called by muse, mutect2, varscan2
- FAM110A | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV55728345, COSV99062253; called by muse, mutect2, varscan2
- FAM110C | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV59656656; called by muse, mutect2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 30/126 reads (24%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM171A1 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1051211743, COSV100968167; called by muse, mutect2
- FAM193A | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1219632732, COSV100219689, COSV61199537; called by muse, mutect2, varscan2
- FAM3C | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs567599690, COSV63436796; called by muse, varscan2
- FAM71A | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 38/132 reads (29%) | catalogued as rs775317074, COSV54236719; called by muse, mutect2, varscan2
- FAN1 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV62950366, COSV62952410; called by muse, varscan2
- FANCL | c.836G>A p.S279N | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52078460; called by muse, mutect2, varscan2
- FANK1 | c.466T>C p.Y156H | Missense Mutation (SNP) | VAF 101/402 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs1360054468, COSV64157263; called by muse, mutect2, varscan2
- FAT1 | c.8799del p.G2934Vfs*3 | Frame Shift Del (DEL) | VAF 52/176 reads (30%) | catalogued as rs113224498; called by mutect2, pindel, varscan2
- FAT1 | c.4089dup p.T1364Yfs*8 | Frame Shift Ins (INS) | VAF 37/172 reads (22%) | catalogued as rs1279779959; called by mutect2, pindel, varscan2
- FBLN2 | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as rs549749793, COSV55491959; called by muse, mutect2, varscan2
- FBN2 | c.4307G>T p.C1436F | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52549039; called by muse, varscan2
- FBN2 | c.2391T>A p.S797R | Missense Mutation (SNP) | VAF 107/405 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.243); catalogued as COSV52549052; called by muse, mutect2, varscan2
- FBXL18 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV66107937; called by muse, mutect2, varscan2
- FBXO43 | c.1898C>G p.T633S | Missense Mutation (SNP) | VAF 163/230 reads (71%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV71055715; called by muse, mutect2, varscan2
- FBXO9 | c.438C>T p.Y146= | Splice Region (SNP) | VAF 30/117 reads (26%) | catalogued as COSV55057727; called by muse, mutect2, varscan2
- FBXW11 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as COSV51614469; called by muse, mutect2, varscan2
- FCAR | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.178); catalogued as COSV62028776, COSV62032151; called by muse, mutect2
- FCRL1 | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV63827434, COSV63827955; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 46/260 reads (18%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FFAR2 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs774217360, COSV55832768; called by muse, mutect2, varscan2
- FFAR3 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100588153; called by muse, mutect2, varscan2
- FGD5 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as COSV53254200; called by muse, mutect2, varscan2
- FGD5 | c.3755G>A p.G1252D | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs1193473779, COSV53250289; called by muse, mutect2, varscan2
- FGG | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 117/432 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs750711649, COSV60194984; called by muse, mutect2, varscan2
- FHOD1 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50772594; called by muse, mutect2
- FIBP | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100327253; called by muse, mutect2
- FITM1 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as COSV99246120; called by muse, mutect2, varscan2
- FLOT2 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67529593; called by muse, mutect2, varscan2
- FN1 | c.6923G>T p.W2308L (on ENST00000359671 / NM_001365524.2; = p.W2277L on NM_002026.4) | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60565874; called by muse, mutect2, varscan2
- FN3K | c.762del p.F255Sfs*32 | Frame Shift Del (DEL) | VAF 30/130 reads (23%) | catalogued as rs768699900; called by mutect2, pindel, varscan2
- FNIP1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1488977967, COSV57193641; called by muse, mutect2
- FPGT | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1325482770, COSV63846206; called by muse, mutect2
- FRMD6 | c.1108G>A p.G370R (on ENST00000344768 / NM_001267046.2; = p.G362R on NM_152330.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs774320055, COSV61091253; called by muse, mutect2, varscan2
- FRMPD1 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs550566906, COSV66700934; called by muse, mutect2, varscan2
- FSTL1 | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 100/330 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55237664; called by muse, varscan2
- FTSJ3 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.616); catalogued as COSV63791613; called by muse, mutect2, varscan2
- FUBP3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs903333957, COSV60516318, COSV60516888; called by muse, mutect2, varscan2
- FUT3 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 122/697 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs753252962, COSV99744432; called by muse, varscan2
- FUT8 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs771685724, COSV61292207; called by muse, mutect2, varscan2
- FXR2 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 48/164 reads (29%) | catalogued as rs776594616, COSV51521116; called by muse, mutect2, varscan2
- FYB2 | c.1851dup p.E618Rfs*6 | Frame Shift Ins (INS) | VAF 137/285 reads (48%) | catalogued as rs751048223; called by mutect2, varscan2
- FZD1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55313773; called by muse, mutect2, varscan2
- GABRA4 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 53/219 reads (24%) | catalogued as COSV51936333, COSV99974661; called by muse, mutect2, varscan2
- GABRG3 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV61510881; called by muse, mutect2, varscan2
- GALNT7 | c.1121T>G p.L374R | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV99397135; called by muse, mutect2
- GARNL3 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 115/418 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs756264516, COSV59223438; called by muse, mutect2, varscan2
- GARNL3 | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as rs1402148812, COSV59231343; called by muse, mutect2, varscan2
- GATA1 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs782299679, COSV64963758, COSV64964273; called by muse, mutect2, varscan2
- GATAD2A | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs982750405, COSV53076841; called by muse, mutect2, varscan2
- GBE1 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 101/379 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780431086, COSV70097934; called by muse, mutect2, varscan2
- GCC2 | c.2583_2585del p.L862del | In Frame Del (DEL) | VAF 78/337 reads (23%) | catalogued as rs747772330; called by pindel, varscan2
- GCN1 | c.7090C>T p.R2364C | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765028391, COSV56108829; called by muse, mutect2, varscan2
- GCN1 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.362); catalogued as rs1464331655, COSV100324879; called by muse, mutect2
- GCNT3 | c.941A>C p.K314T | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.054); catalogued as COSV68532645; called by muse, mutect2, varscan2
- GDF1 | c.38T>A p.L13H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.28); catalogued as rs772809060, COSV99439130; called by muse, varscan2
- GDPD5 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369648232; called by muse, mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 10/19 reads (53%) | catalogued as rs771881138; called by mutect2, varscan2
- GIPC3 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59261040; called by muse, mutect2, varscan2
- GLI4 | c.950A>G p.H317R | Missense Mutation (SNP) | VAF 95/155 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60682960; called by muse, mutect2, varscan2
- GLIS3 | c.1517del p.K506Sfs*145 | Frame Shift Del (DEL) | VAF 133/516 reads (26%) | catalogued as COSV100173970; called by mutect2, pindel, varscan2
- GLMP | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | catalogued as rs376941297, COSV55297710; called by muse, mutect2, varscan2
- GLP2R | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52330272; called by muse, mutect2, varscan2
- GLT8D1 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV56476985; called by muse, mutect2, varscan2
- GLYCTK | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1162085369, COSV59794909; called by muse, mutect2, varscan2
- GMEB1 | c.526A>G p.N176D | Missense Mutation (SNP) | VAF 101/411 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV53797432; called by muse, mutect2, varscan2
- GMPPB | c.266C>A p.P89H | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57540454; called by muse, mutect2, varscan2
- GNA12 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51746201; called by muse, mutect2, varscan2
- GNAQ | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54112810, COSV54117130; called by muse, mutect2
- GNAS | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs893327176, COSV55674968; called by muse, mutect2, varscan2
- GNG7 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as rs1221437931, COSV66288550; called by muse, mutect2, varscan2
- GNPTG | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764395288, COSV50190975; called by muse, mutect2, varscan2
- GOLGA1 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 180/720 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs182309185, COSV63024225; called by muse, varscan2
- GOLGA4 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 83/325 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs768808136, COSV62710279; called by muse, mutect2, varscan2
- GOLGA4 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 159/544 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759277142, COSV62714346; called by muse, mutect2, varscan2
- GOLGA4 | c.3902A>C p.E1301A | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV62714352; called by muse, mutect2, varscan2
- GORASP2 | c.1251del p.T418Lfs*74 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as COSV52202002; called by mutect2, pindel, varscan2
- GPC1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV50867338; called by muse, mutect2
- GPLD1 | c.2479C>T p.R827* | Nonsense Mutation (SNP) | VAF 46/139 reads (33%) | catalogued as COSV99218684, COSV99218819; called by muse, mutect2, varscan2
- GPM6A | c.185T>C p.F62S | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54563430; called by muse, mutect2, varscan2
- GPR108 | c.1568A>G p.D523G (on ENST00000264080 / NM_001080452.1; = p.D281G on NM_020171.2) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV51186642; called by muse, mutect2, varscan2
- GPR137 | c.733del p.Q245Rfs*21 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as COSV57403226; called by mutect2, pindel, varscan2
- GPR139 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as rs781371656, COSV58502271; called by muse, varscan2
- GPR149 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.469); catalogued as COSV101078251; called by muse, mutect2
- GPR31 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV64762110; called by muse, mutect2, varscan2
- GPX1 | c.468T>A p.C156* | Nonsense Mutation (SNP) | VAF 91/275 reads (33%) | catalogued as rs750674238, COSV69043799; called by muse, mutect2, varscan2
- GRAMD1B | c.1171C>A p.L391I | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1183079679, COSV59211499; called by muse, mutect2, varscan2
- GRIK5 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53475475; called by muse, mutect2, varscan2
- GRIN3B | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs746593296, COSV52264006; called by muse, mutect2, varscan2
- GRM6 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as rs1262310538, COSV99179519; called by muse, mutect2, varscan2
- GRM8 | c.2161A>G p.I721V | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV100281689; called by muse, mutect2, varscan2
- GSAP | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 102/378 reads (27%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as rs781694106, COSV99990061; called by muse, mutect2, varscan2
- GSE1 | c.227-1G>T p.X76_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV53675786; called by muse, mutect2, varscan2
- GSTA1 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 96/462 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs1131849, COSV58017205; called by muse, varscan2
- GSTA1 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58017213; called by muse, varscan2
- GTF3C1 | c.6082del p.V2028Sfs*25 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as COSV62241645; called by mutect2, pindel, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 180/671 reads (27%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GTPBP1 | c.1665G>C p.Q555H | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV53288299; called by muse, mutect2, varscan2
- GUF1 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 53/137 reads (39%) | catalogued as rs769392101, COSV55784905; called by muse, mutect2, varscan2
- H2BC3 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs756126649, COSV63551146; called by muse, mutect2, varscan2
- HAGHL | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs747918697; called by mutect2, varscan2
- HAVCR2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs147605860; called by muse, mutect2, varscan2
- HEATR1 | c.6063G>A p.M2021I | Missense Mutation (SNP) | VAF 40/545 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV100857561; called by muse, mutect2
- HELZ | c.2981G>A p.S994N | Missense Mutation (SNP) | VAF 28/649 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100698608; called by muse, mutect2
- HERC1 | c.5645G>A p.S1882N | Missense Mutation (SNP) | VAF 94/310 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV71250729; called by muse, mutect2, varscan2
- HEYL | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs368236989; called by muse, mutect2, varscan2
- HGF | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55958254; called by muse, mutect2, varscan2
- HIVEP1 | c.3091del p.R1031Gfs*4 | Frame Shift Del (DEL) | VAF 31/156 reads (20%) | catalogued as COSV65102133; called by mutect2, pindel, varscan2
- HIVEP1 | c.6128C>T p.A2043V | Missense Mutation (SNP) | VAF 237/766 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.883); catalogued as COSV65105579; called by muse, mutect2, varscan2
- HIVEP3 | c.1487G>T p.S496I | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56025224; called by muse, mutect2, varscan2
- HK1 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs770084986, COSV53853784; called by muse, mutect2, varscan2
- HLA-C | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as rs281860449, COSV66119670; called by mutect2, varscan2
- HLA-DOA | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs915943308, COSV57715785; called by muse, mutect2, varscan2
- HMGA1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.036); catalogued as COSV61029062; called by muse, mutect2, varscan2
- HMMR | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV62375678; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXA6 | c.63_65del p.F21del | In Frame Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs776564519; called by pindel, varscan2
- HOXD10 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 35/163 reads (21%) | catalogued as COSV99981851; called by muse, mutect2, varscan2
- HPN | c.1053C>T p.G351= | Splice Region (SNP) | VAF 46/146 reads (32%) | catalogued as rs372630062; called by muse, mutect2, varscan2
- HPS1 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV57270739; called by muse, mutect2, varscan2
- HRH1 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370754604, COSV67955545; called by muse, mutect2, varscan2
- HSD3B7 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs560826820, COSV52680927; called by muse, mutect2, varscan2
- HSF2 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 53/238 reads (22%) | catalogued as COSV63774721; called by muse, mutect2, varscan2
- HSP90AA1 | c.1906A>G p.I636V | Missense Mutation (SNP) | VAF 48/632 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV53487730; called by muse, mutect2
- HSPA12B | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53924483, COSV53925640; called by muse, mutect2, varscan2
- HSPG2 | c.6860C>T p.A2287V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.426); catalogued as rs1159326179, COSV101020532; called by muse, mutect2, varscan2
- HTR1A | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as COSV60503362; called by muse, mutect2, varscan2
- HTR1A | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60503372; called by muse, mutect2, varscan2
- HTR1B | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV100885375; called by muse, mutect2, varscan2
- HTR3B | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99491852; called by muse, mutect2, varscan2
- HTR6 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs775112428, COSV53878172, COSV99230555; called by muse, mutect2, varscan2
- ICAM2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs565156038, COSV99856855; called by muse, mutect2, varscan2
- IDH1 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs781398075, COSV61644872; called by muse, mutect2, varscan2
- IDUA | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV56107309; called by muse, mutect2
- IFNGR2 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs369753667; called by muse, mutect2, varscan2
- IGDCC4 | c.2613del p.T872Qfs*11 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | catalogued as COSV61539288; called by mutect2, pindel, varscan2
- IGHG4 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 53/299 reads (18%) | catalogued as rs752177177; called by muse, mutect2, varscan2
- IL17RB | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV55474696; called by muse, mutect2, varscan2
- IL17REL | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs754560571, COSV58009299; called by muse, mutect2, varscan2
- IL3RA | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 52/184 reads (28%) | catalogued as COSV58433698; called by muse, mutect2, varscan2
- INA | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs757776233, COSV63976619; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INPP4B | c.2452dup p.R818Kfs*26 | Frame Shift Ins (INS) | VAF 51/195 reads (26%) | catalogued as rs772784869; called by mutect2, varscan2
- INSM2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763893619, COSV99354010; called by muse, mutect2, varscan2
- INSR | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV57174703; called by muse, mutect2, varscan2
- INTS1 | c.5462T>C p.L1821P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV67180162; called by muse, varscan2
- INTS8 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 190/272 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58253771; called by muse, mutect2, varscan2
- IQSEC3 | c.2140C>T p.R714C (on ENST00000538872 / NM_001170738.2; = p.R411C on NM_015232.1) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs150994565, COSV100407647; called by muse, mutect2, varscan2
- ISM2 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV53633860, COSV53637437; called by muse, mutect2, varscan2
- ISYNA1 | c.1387C>A p.L463I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV54212781; called by muse, mutect2, varscan2
- ITGA10 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374418570; called by muse, mutect2, varscan2
- ITGA11 | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs377427762; called by muse, mutect2, varscan2
- ITGA3 | c.3076G>A p.A1026T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as rs778123052, COSV50347617; called by muse, mutect2, varscan2
- ITGB2 | c.306del p.V103* | Frame Shift Del (DEL) | VAF 51/178 reads (29%) | catalogued as COSV56612327; called by mutect2, pindel, varscan2
- ITGB4 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.065); catalogued as COSV52334163; called by muse, mutect2, varscan2
- ITPKB | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.011); catalogued as rs541837953, COSV55271107; called by muse, mutect2, varscan2
- JADE1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99885541; called by muse, mutect2, varscan2
- JAKMIP1 | c.1101+2T>C p.X367_splice | Splice Site (SNP) | VAF 54/230 reads (23%) | catalogued as COSV99289084; called by muse, mutect2, varscan2
- JMJD6 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs374399276; called by muse, mutect2, varscan2
- JMJD8 | c.221A>T p.N74I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99555530; called by muse, mutect2
- KAT2A | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52425113; called by muse, mutect2, varscan2
- KAT6B | c.5728A>G p.S1910G | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99767652; called by muse, mutect2
- KATNB1 | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV65562140; called by muse, varscan2
- KATNIP | c.4450-1G>T p.X1484_splice | Splice Site (SNP) | VAF 51/189 reads (27%) | catalogued as COSV55193508; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNA6 | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1221274206, COSV54978409; called by muse, mutect2, varscan2
- KCNB1 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1430893485, COSV65571311; called by muse, mutect2, varscan2
- KCNC3 | c.1880del p.G627Efs*27 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1159900432; called by mutect2, varscan2
- KCNG2 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100301708; called by muse, mutect2, varscan2
- KCNH3 | c.922C>A p.L308M | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99234977; called by muse, mutect2, varscan2
- KCNJ4 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV57859103; called by muse, mutect2, varscan2
- KCNMB3 | c.555del p.S187Hfs*16 | Frame Shift Del (DEL) | VAF 61/514 reads (12%) | catalogued as rs776053179; called by mutect2, pindel, varscan2
- KCNS3 | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 37/176 reads (21%) | catalogued as COSV58409149; called by muse, mutect2, varscan2
- KCNV1 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 117/180 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as COSV52087607, COSV52089586; called by muse, mutect2, varscan2
- KCTD3 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52071523; called by muse, mutect2, varscan2
- KCTD8 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63598349; called by muse, mutect2, varscan2
- KDELR1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV58103085; called by muse, mutect2, varscan2
- KIAA1109 | c.11147G>A p.G3716D | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as COSV99151040; called by muse, mutect2, varscan2
- KIAA1217 | c.4859C>G p.A1620G | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100286891, COSV56825128; called by muse, mutect2, varscan2
- KIAA1217 | c.5207G>A p.R1736H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as rs759096904, COSV56825133; called by muse, mutect2, varscan2
- KIAA1549 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.27); catalogued as rs376519473; called by muse, mutect2, varscan2
- KIAA1549 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs562166819, COSV54331609; called by muse, mutect2, varscan2
- KIAA1755 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs746025973, COSV54076680; called by muse, mutect2, varscan2
- KIF12 | c.1622G>A p.G541D (on ENST00000640217; = p.G403D on NM_138424.1) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as COSV65118552; called by muse, mutect2, varscan2
- KIF13A | c.1212A>T p.K404N | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV52461728, COSV52468182; called by muse, varscan2
- KIF13B | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1478637697, COSV101568692; called by muse, mutect2
- KIF2B | c.201dup p.G68Rfs*5 | Frame Shift Ins (INS) | VAF 32/140 reads (23%) | catalogued as rs971647972; called by pindel, varscan2
- KIF9 | c.1714G>A p.D572N (on ENST00000265529 / NM_001377474.1; = p.D507N on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs745616983, COSV55519233; called by muse, mutect2, varscan2
- KLHL42 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 197/391 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.099); catalogued as rs1192326890, COSV67145829; called by muse, mutect2, varscan2
- KLKB1 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53000153; called by muse, mutect2, varscan2
- KMT2D | c.12875C>T p.P4292L | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV56493218; called by muse, mutect2, varscan2
- KMT2D | c.12743C>T p.T4248I | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV56493231; called by muse, mutect2, varscan2
- KRBA1 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as rs374134774; called by muse, mutect2, varscan2
- KRT23 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 142/539 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs141349810; called by muse, mutect2, varscan2
- KRT75 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV99359309; called by muse, mutect2
- KRTAP12-3 | c.237dup p.C80Lfs*34 | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | catalogued as rs782171993; called by mutect2, varscan2
- KRTAP19-6 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV61844441; called by muse, mutect2, varscan2
- KYAT3 | c.1346G>T p.W449L | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV53106413; called by muse, mutect2, varscan2
- LAMA1 | c.6184A>G p.M2062V | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV67545285; called by muse, varscan2
- LAMA1 | c.3450C>A p.C1150* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | catalogued as rs769949964, COSV101055664; called by muse, mutect2, varscan2
- LAMA4 | c.4346G>A p.R1449Q (on ENST00000230538 / NM_001105206.3; = p.R1442Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/324 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs782695193, COSV100039885, COSV57906158; called by muse, mutect2, varscan2
- LAMA5 | c.10271G>A p.R3424H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs767793690, COSV53374355; called by muse, mutect2, varscan2
- LBP | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs545550026, COSV54141355; called by muse, mutect2, varscan2
- LDHAL6B | c.509T>A p.I170N | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55697001; called by muse, mutect2, varscan2
- LENG8 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs141640196; called by muse, mutect2, varscan2
- LGALS3 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs1370432577, COSV54306608; called by muse, mutect2
- LGR6 | c.511G>A p.D171N (on ENST00000367278 / NM_001017403.1; = p.D119N on NM_021636.3) | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs1352975816, COSV55167731; called by muse, mutect2, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs775423572; called by mutect2, varscan2
- LIN54 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV61203139; called by muse, mutect2, varscan2
- LIPT1 | c.1105dup p.I369Nfs*2 | Frame Shift Ins (INS) | VAF 60/283 reads (21%) | catalogued as rs754457101; called by mutect2, pindel, varscan2
- LMF2 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.806); catalogued as rs144342127; called by muse, mutect2, varscan2
- LOXL3 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762623422, COSV51216311; called by muse, mutect2, varscan2
- LPAR2 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1324354730, COSV52559255; called by muse, mutect2, varscan2
- LPCAT4 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59219654; called by muse, mutect2, varscan2
- LRFN5 | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 95/403 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53278124; called by muse, mutect2, varscan2
- LRP1 | c.10954C>T p.R3652W | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs1272985609, COSV54522319; called by muse, mutect2, varscan2
- LRP1B | c.2489G>T p.G830V | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV67199582, COSV67281776; called by muse, mutect2, varscan2
- LRP2 | c.10724A>G p.H3575R | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99787337; called by muse, mutect2, varscan2
- LRP4 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101066422, COSV101066908; called by muse, mutect2, varscan2
- LRP6 | c.2543C>T p.T848M | Missense Mutation (SNP) | VAF 65/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53791010; called by muse, mutect2, varscan2
- LRRN1 | c.1403C>A p.T468N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV60016714; called by muse, mutect2, varscan2
- LRRTM1 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.27); catalogued as rs758815898, COSV54447594; called by muse, mutect2, varscan2
- LRWD1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.837); catalogued as rs1302284212, COSV52962494; called by muse, mutect2, varscan2
- LSS | c.1317G>T p.K439N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV62703083; called by muse, mutect2, varscan2
- LYN | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 108/268 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV70206528; called by muse, mutect2, varscan2
- LYSMD2 | c.323T>G p.F108C | Missense Mutation (SNP) | VAF 30/345 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51057256; called by muse, mutect2
- MAB21L2 | c.560G>T p.W187L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58263847; called by muse, mutect2, varscan2
- MAB21L2 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58263860; called by muse, mutect2, varscan2
- MAGEB4 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs142718587, COSV64397843; called by muse, mutect2, varscan2
- MAGI2 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.715); catalogued as rs1430461191, COSV62643246; called by muse, mutect2, varscan2
- MAP10 | c.269del p.N90Tfs*32 | Frame Shift Del (DEL) | VAF 44/217 reads (20%) | catalogued as rs1558360474; called by mutect2, pindel, varscan2
- MAP2 | c.953A>C p.Q318P | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.133); catalogued as COSV52310973; called by muse, mutect2, varscan2
- MAP3K3 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs756808678, COSV62282057; called by muse, mutect2, varscan2
- MAP3K5 | c.2539G>A p.A847T | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62890601; called by muse, mutect2
- MAP7D1 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.204); catalogued as rs1379013966, COSV60219116; called by muse, mutect2, varscan2
- MAPK8IP2 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV99151176; called by muse, mutect2
- MAST4 | c.4555G>T p.G1519C (on ENST00000403625 / NM_001164664.2; = p.G1330C on NM_015183.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55144950; called by muse, mutect2, varscan2
- MBD1 | c.1481C>T p.A494V (on ENST00000269468 / NM_001323950.1; = p.A438V on NM_015844.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as COSV53999019, COSV54008353, COSV99495844; called by muse, mutect2, varscan2
- MBD1 | c.423_424del p.D143Wfs*29 | Frame Shift Del (DEL) | VAF 34/145 reads (23%) | catalogued as COSV54007993; called by mutect2, pindel, varscan2
- MBOAT1 | c.117C>A p.C39* | Nonsense Mutation (SNP) | VAF 14/138 reads (10%) | catalogued as COSV61128372; called by muse, mutect2
- MCM3AP | c.5803C>T p.Q1935* | Nonsense Mutation (SNP) | VAF 38/114 reads (33%) | catalogued as COSV52446452; called by muse, mutect2, varscan2
- MCRS1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as rs1280379106, COSV59461990; called by muse, mutect2, varscan2
- MED12L | c.4676A>G p.H1559R | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1418413435; called by muse, mutect2
- MED12L | c.4901T>C p.V1634A | Missense Mutation (SNP) | VAF 125/426 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV56400425; called by muse, mutect2, varscan2
- MED14 | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 106/207 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV61356152; called by muse, mutect2, varscan2
- MEIS2 | c.104del p.P35Rfs*5 (on ENST00000561208 / NM_170675.5; = p.P22Rfs*5 on NM_002399.3) | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as COSV54933605; called by mutect2, pindel
- METTL1 | c.82A>G p.N28D | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55745921; called by muse, mutect2, varscan2
- MFAP3 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59457701; called by muse, mutect2, varscan2
- MFN2 | c.2000A>C p.E667A | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.497); catalogued as COSV52425980; called by muse, mutect2, varscan2
- MFSD14B | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 124/426 reads (29%) | catalogued as rs776521068, COSV64702253; called by muse, mutect2, varscan2
- MFSD6L | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs1453734798, COSV61006514; called by muse, mutect2
- MGAM | c.3483+1del | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | catalogued as COSV72076311; called by mutect2, pindel, varscan2
- MIB2 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as rs757806716, COSV61543577; called by muse, mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs765803753; called by mutect2, pindel
- MIDEAS | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs1042455853, COSV54099785, COSV99678775; called by muse, mutect2, varscan2
- MIOX | c.703T>C p.C235R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs767033338, COSV99326752; called by muse, mutect2
- MIS18A | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.067); catalogued as COSV51590609; called by muse, mutect2, varscan2
- MLLT3 | c.1699A>C p.T567P | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs764224947, COSV100580830; called by muse, varscan2
- MLXIP | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1304595816, COSV59838399; called by muse, mutect2, varscan2
- MMP2 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs759812293, COSV54602758; called by muse, mutect2, varscan2
- MOB2 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.091); catalogued as rs369650668; called by muse, mutect2, varscan2
- MPDZ | c.5462G>A p.S1821N (on ENST00000319217 / NM_001330637.2; = p.S1788N on NM_001261406.2 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100056443; called by muse, mutect2, varscan2
- MPEG1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs377026755; called by muse, mutect2, varscan2
- MRAP2 | c.186dup p.V63Cfs*40 | Frame Shift Ins (INS) | VAF 403/1699 reads (24%) | catalogued as rs758625941; called by mutect2, pindel, varscan2
- MRGPRX1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.365); catalogued as rs1305417663, COSV57107474; called by muse, mutect2, varscan2
- MSANTD1 | c.320G>T p.R107M | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70873369; called by muse, mutect2, varscan2
- MST1R | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV56565310, COSV56574973; called by muse, mutect2, varscan2
- MTERF2 | c.647A>C p.N216T | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV53528435; called by muse, mutect2, varscan2
- MTMR3 | c.1813del p.L605* | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | catalogued as COSV60305229; called by mutect2, pindel, varscan2
- MTMR6 | c.1735A>C p.N579H | Missense Mutation (SNP) | VAF 93/320 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); catalogued as COSV67810033; called by muse, mutect2, varscan2
- MTRF1L | c.557del p.G186Vfs*8 | Frame Shift Del (DEL) | VAF 44/267 reads (16%) | catalogued as rs1438686273; called by mutect2, pindel, varscan2
- MUC16 | c.26015C>A p.P8672H | Missense Mutation (SNP) | VAF 134/450 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV67474707, COSV67498934; called by muse, mutect2, varscan2
- MUC16 | c.6670G>A p.A2224T | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs373571868, COSV67471822, COSV67479502; called by muse, mutect2, varscan2
- MUC5AC | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); catalogued as COSV100650562; called by muse, mutect2, varscan2
- MUC5B | c.13813C>T p.P4605S | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); catalogued as COSV101500178; called by muse, mutect2, varscan2
- MUC6 | c.3928G>T p.A1310S | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs200318996, COSV104436528, COSV70151278; called by muse, mutect2
- MUSK | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as rs777107917, COSV51898717; ClinVar: uncertain significance; called by muse, mutect2
- MYF5 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.57); catalogued as COSV57354909, COSV99953460; called by muse, mutect2, varscan2
- MYH11 | c.5093C>T p.A1698V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as rs779639232, COSV100260536, COSV55545437; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH15 | c.3711G>T p.Q1237H | Missense Mutation (SNP) | VAF 41/704 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV99842758; called by muse, mutect2
- MYH4 | c.4147G>A p.A1383T | Missense Mutation (SNP) | VAF 118/432 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs1256887047, COSV55118883; called by muse, varscan2
- MYH6 | c.4907G>A p.R1636H | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as rs746448302, COSV62452171; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.4091G>A p.R1364Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs199900154; called by muse, mutect2, varscan2
- MYH8 | c.5580T>A p.D1860E | Missense Mutation (SNP) | VAF 33/375 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV67973904; called by muse, mutect2
- MYH9 | c.4306G>A p.A1436T | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs373912645, CM147352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5C | c.2371C>T p.R791W | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs189764725, COSV55912813; called by muse, mutect2, varscan2
- MZT2A | c.208del p.L70Sfs*16 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs770250515; called by mutect2, varscan2
- N4BP2 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1349460352, COSV54707840; called by muse, mutect2, varscan2
- NAA35 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs776821188, COSV64486841; called by muse, mutect2, varscan2
- NAB1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs754331585, COSV61609246; called by muse, mutect2, varscan2
- NAP1L3 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV59078013; called by muse, mutect2, varscan2
- NAT2 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752501077, COSV54063312; called by muse, mutect2, varscan2
- NAV2 | c.6920G>A p.R2307H (on ENST00000396087 / NM_001244963.2; = p.R2248H on NM_145117.5) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs757104715, COSV100216329, COSV60665583; called by muse, mutect2, varscan2
- NAV3 | c.6617G>A p.R2206H (on ENST00000397909 / NM_001024383.2; = p.R2184H on NM_014903.6) | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1007506972, COSV57098750; called by muse, mutect2, varscan2
- NCOR1 | c.7022G>T p.G2341V | Missense Mutation (SNP) | VAF 106/359 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51999755; called by muse, mutect2, varscan2
- NDC1 | c.859T>C p.S287P | Missense Mutation (SNP) | VAF 20/403 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV99323454; called by muse, mutect2
- NEK2 | c.908T>C p.L303S | Missense Mutation (SNP) | VAF 34/471 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100878563; called by muse, mutect2
- NEK5 | c.1856A>G p.Y619C | Missense Mutation (SNP) | VAF 246/446 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100839271, COSV62882288; called by muse, mutect2, varscan2
- NEK8 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs1238581801, COSV52049302; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 41/106 reads (39%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEXMIF | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV50172284; called by muse, mutect2
- NFIX | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as rs1256133151, COSV62176628; called by muse, mutect2, varscan2
- NID1 | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs1460270506, COSV51630148; called by muse, mutect2, varscan2
- NIPA2 | c.98dup p.L35Pfs*21 | Frame Shift Ins (INS) | VAF 33/152 reads (22%) | catalogued as rs145147241; called by mutect2, varscan2
- NIT2 | c.126+2T>G p.X42_splice | Splice Site (SNP) | VAF 14/57 reads (25%) | catalogued as COSV67630846; called by muse, mutect2, varscan2
- NKAP | c.497A>T p.E166V | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV65057081; called by muse, mutect2, varscan2
- NKAP | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as rs1275490009, COSV65057085; called by muse, mutect2, varscan2
- NKX2-1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1447379564, CM086002, COSV61390372; called by muse, mutect2, varscan2
- NKX2-5 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61300119; called by muse, mutect2, varscan2
- NLGN4Y | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 129/256 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52971833; called by muse, mutect2, varscan2
- NLRP2 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs763533364, COSV54756745; called by muse, mutect2, varscan2
- NLRP3 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV60232152; called by muse, mutect2, varscan2
- NLRP7 | c.1780A>T p.I594F | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV60183051; called by muse, mutect2, varscan2
- NMUR2 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1159850801, COSV54923361; called by muse, mutect2, varscan2
- NOL12 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 16/213 reads (8%) | catalogued as rs1415909970, COSV100767136; called by muse, mutect2
- NOP2 | c.938G>A p.R313Q (on ENST00000322166 / NM_001258308.2; = p.R309Q on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185687202; called by muse, mutect2, varscan2
- NOP58 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs771268418, COSV51899062; called by muse, varscan2
- NOS3 | c.2347C>A p.L783M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV52496762; called by muse, mutect2, varscan2
- NOTCH2 | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 112/405 reads (28%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.925); catalogued as COSV56708630; called by muse, mutect2, varscan2
- NOX5 | c.2216_2218del p.F739del | In Frame Del (DEL) | VAF 24/103 reads (23%) | catalogued as rs764708048; called by pindel, varscan2
- NPLOC4 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.039); catalogued as rs758048463, COSV58620419; called by muse, mutect2, varscan2
- NRG3 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 134/540 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs373607716; called by muse, varscan2
- NRG3 | c.1568C>T p.T523M | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV64587769; called by muse, mutect2, varscan2
- NRROS | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs530581190, COSV60745744; called by muse, mutect2, varscan2
- NSL1 | c.499+2T>C p.X167_splice | Splice Site (SNP) | VAF 34/598 reads (6%) | catalogued as COSV65330344; called by muse, mutect2
- NSMF | c.1568T>C p.L523P (on ENST00000371475 / NM_001130969.3; = p.L521P on NM_015537.4) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99689114; called by muse, mutect2, varscan2
- NT5C1A | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775212324, COSV52493502; called by muse, mutect2, varscan2
- NTRK1 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs139875058; called by muse, mutect2, varscan2
- NTRK3 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV58147402; called by muse, mutect2
- NUDT1 | c.472G>A p.G158R (on ENST00000397048 / NM_198952.1; = p.G135R on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182662727, COSV56130751; called by muse, mutect2, varscan2
- NUDT18 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 110/155 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57161001; called by muse, mutect2, varscan2
- NUP153 | c.778del p.Y260Ifs*14 | Frame Shift Del (DEL) | VAF 44/226 reads (19%) | catalogued as COSV50448762; called by pindel, varscan2
- NUP160 | c.2676G>A p.Q892= | Splice Region (SNP) | VAF 101/449 reads (22%) | catalogued as COSV65856423; called by muse, mutect2, varscan2
- NUP205 | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 89/359 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1334521753, COSV53656116; called by muse, mutect2, varscan2
- NUP205 | c.4092G>T p.E1364D | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99606694; called by muse, mutect2
- NUP210 | c.1921C>A p.L641M | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as COSV54415156; called by muse, mutect2, varscan2
- NUP210 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs777670578, COSV54415178; called by muse, mutect2, varscan2
- NYAP1 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55722612; called by muse, mutect2, varscan2
- NYNRIN | c.5387A>G p.E1796G | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.227); catalogued as COSV66845576; called by muse, varscan2
- ODF2 | c.2439T>A p.Y813* (on ENST00000434106 / NM_153433.2; = p.Y789* on NM_002540.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/150 reads (15%) | catalogued as COSV59411124; called by muse, mutect2, varscan2
- ODR4 | c.1201_1203del p.S401del | In Frame Del (DEL) | VAF 137/562 reads (24%) | catalogued as rs1558101662; called by pindel, varscan2
- OGFRL1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 97/340 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs773746901, COSV100965737, COSV64972585; called by muse, mutect2, varscan2
- OLA1 | c.391_393del p.D131del | In Frame Del (DEL) | VAF 92/392 reads (23%) | catalogued as rs1251931518; called by pindel, varscan2
- OLIG3 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62988361; called by muse, mutect2, varscan2
- OMD | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1452978202, COSV65020560; called by muse, mutect2, varscan2
- OPRL1 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1239386537, COSV61093212; called by muse, mutect2
- OPTN | c.76dup p.H26Pfs*37 | Frame Shift Ins (INS) | VAF 11/49 reads (22%) | catalogued as rs753966040; called by mutect2, varscan2
- OR10G7 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.075); catalogued as COSV100389828; called by muse, mutect2
- OR10H2 | c.559T>A p.L187M | Missense Mutation (SNP) | VAF 137/403 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59947228; called by muse, mutect2, varscan2
- OR13C3 | c.961C>A p.L321M | Missense Mutation (SNP) | VAF 112/436 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as COSV66166413; called by muse, mutect2, varscan2
- OR2H1 | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 114/375 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as rs370239828; called by muse, mutect2, varscan2
- OR2T10 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.119); catalogued as COSV57898639; called by muse, mutect2, varscan2
- OR52B4 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV68769596; called by muse, mutect2, varscan2
- OR5K2 | c.457A>C p.N153H | Missense Mutation (SNP) | VAF 119/553 reads (22%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.947); catalogued as COSV71143567; called by muse, mutect2, varscan2
- OR6K6 | c.155G>A p.G52D (on ENST00000368144; = p.G28D on NM_001005184.1) | Missense Mutation (SNP) | VAF 20/399 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.689); catalogued as rs1344315073, COSV100933714; called by muse, mutect2
- OR7G2 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs372179793; called by muse, mutect2, varscan2
- ORAI2 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.976); catalogued as rs1563639327, COSV62689149; called by muse, mutect2, varscan2
- ORC3 | c.610del p.R204Gfs*16 | Frame Shift Del (DEL) | VAF 42/173 reads (24%) | catalogued as rs1336736903; called by mutect2, varscan2
- OSCP1 | c.610G>T p.G204W (on ENST00000356637 / NM_001330493.1; = p.G194W on NM_145047.5) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52485034; called by muse, mutect2, varscan2
- OSM | c.701G>T p.R234M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53162451; called by muse, mutect2, varscan2
- OTOF | c.2959G>A p.V987I (on ENST00000272371 / NM_194248.3; = p.V240I on NM_004802.4) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs772973509, COSV55523019; called by muse, mutect2, varscan2
- OTOGL | c.1459G>A p.G487S (on ENST00000547103; = p.G478S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/330 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV72007679; called by muse, varscan2
- OTOGL | c.6704G>C p.C2235S (on ENST00000547103; = p.C2226S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54025168; called by muse, mutect2, varscan2
- OXT | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1236413021, COSV54132343; called by muse, mutect2
- PABPC5 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs767399259, COSV57043585; called by muse, mutect2, varscan2
- PACRGL | c.278T>C p.L93S | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54845007; called by muse, mutect2, varscan2
- PACS2 | c.2647G>A p.G883R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs368316410, COSV57657923; called by muse, mutect2, varscan2
- PADI1 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100968445; called by muse, mutect2, varscan2
- PAH | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV61021027, COSV61021233; called by muse, mutect2, varscan2
- PAPPA2 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as rs562267517, COSV62777096; called by muse, mutect2, varscan2
- PARD3B | c.121-1G>T p.X41_splice | Splice Site (SNP) | VAF 67/306 reads (22%) | catalogued as COSV62533644; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 114/420 reads (27%) | catalogued as rs772816756; called by mutect2, varscan2
- PARP6 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV53005480; called by muse, mutect2, varscan2
- PAX3 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV51345491; called by muse, mutect2, varscan2
- PAX6 | c.1142T>C p.M381T | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV99570253; called by muse, varscan2
- PC | c.2651G>A p.G884D | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58994712; called by muse, mutect2, varscan2
- PCDH10 | c.1660C>A p.L554M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52105791; called by muse, mutect2, varscan2
- PCDH15 | c.5087G>A p.C1696Y | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.616); catalogued as rs746157145, COSV57406834; called by muse, mutect2, varscan2
- PCDH7 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.576); catalogued as rs1273170181, COSV100687862; called by muse, mutect2, varscan2
- PCDHA13 | c.727del p.Y243Tfs*7 | Frame Shift Del (DEL) | VAF 23/132 reads (17%) | catalogued as rs1554176407; called by mutect2, pindel, varscan2
- PCDHA6 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); catalogued as COSV65348214, COSV65348221; called by muse, mutect2, varscan2
- PCDHB12 | c.1688A>G p.Y563C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs148692502; called by muse, mutect2, varscan2
- PCDHB5 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs574506353, COSV50653565; called by muse, mutect2
- PCDHGB1 | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV54049677; called by muse, mutect2, varscan2
- PCLO | c.10004C>T p.A3335V | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV61659445; called by muse, mutect2, varscan2
- PCNT | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs537348698, COSV64033770; called by muse, mutect2, varscan2
- PCNT | c.6245A>G p.Y2082C | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV64033776; called by muse, mutect2, varscan2
- PCNX1 | c.4978C>T p.R1660* | Nonsense Mutation (SNP) | VAF 102/395 reads (26%) | catalogued as COSV53096786; called by muse, varscan2
- PDE4D | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as COSV61455804; called by muse, mutect2, varscan2
- PDLIM7 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100730260, COSV62883978; called by muse, mutect2, varscan2
- PDZD3 | c.479G>T p.R160M (on ENST00000531114; = p.R94M on NM_024791.4) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52710598; called by muse, mutect2, varscan2
- PDZD4 | c.1135del p.R379Gfs*28 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | catalogued as COSV51246754; called by mutect2, pindel, varscan2
- PEAK3 | c.21dup p.T8Hfs*18 | Frame Shift Ins (INS) | VAF 32/201 reads (16%) | catalogued as rs1367025070; called by mutect2, pindel, varscan2
- PEG3 | c.4057C>T p.L1353F | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.193); catalogued as rs754025939, COSV55650325; called by muse, mutect2, varscan2
- PER1 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs201015773, COSV57922471; called by muse, mutect2, varscan2
- PER1 | c.2786C>A p.P929Q | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV57922477; called by muse, mutect2, varscan2
- PFKP | c.1241C>A p.A414D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV66902161; called by muse, mutect2, varscan2
- PGS1 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs370134635; called by muse, mutect2, varscan2
- PHACTR2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1212040083, COSV59860243; called by muse, mutect2, varscan2
- PHC2 | c.1398G>T p.Q466H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57108600; called by muse, mutect2
- PHF21B | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.029); catalogued as rs1197836173, COSV57558304; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 36/132 reads (27%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHIP | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1562217773, COSV51507630; called by muse, mutect2, varscan2
- PHKA2 | c.2087C>T p.T696M | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs759326764, COSV66056785; called by muse, mutect2, varscan2
- PHKG1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV51918913, COSV51919356; called by muse, mutect2, varscan2
- PHLDB1 | c.3764G>A p.S1255N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV61882351; called by muse, mutect2, varscan2
- PHYHD1 | c.475G>A p.A159T (on ENST00000372592 / NM_001100876.2; = p.T151= on NM_174933.4) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs746672381, COSV58280746; called by muse, mutect2, varscan2
- PIK3AP1 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs952542746, COSV59536858; called by muse, mutect2, varscan2
- PINK1 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs184043309, COSV58632253; ClinVar: uncertain significance; called by mutect2, varscan2
- PIP4K2A | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs771178304, COSV64862383; called by muse, mutect2, varscan2
- PKN3 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV52580207; called by muse, mutect2, varscan2
1,050 further variants in this file (602 protein-altering or splice-affecting, 410 silent, 38 other) are not listed here.
